CCDI case PBBLMW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/101a0630-5afc-45b2-8d95-55189bf647ab

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 6.8 years (2,497 days).

Biospecimens (3 samples)
- Sample 0DC45W: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DC460: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DC462: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
